TARGET case TARGET-30-PASTTX — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ec2d3e1f-cb31-5e54-b381-7888d438bb86

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 0 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C74.1; Tissue or organ of origin: Medulla of adrenal gland; Classification of tumor: primary; Age at diagnosis: 0.6 years (214 days); Year of diagnosis: 2009; Days to last follow up: 2,461 days (6.7 years); Cog neuroblastoma risk group: Low Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 1; Mitosis karyorrhexis index: Low.
   Pathology details: Percent tumor nuclei: 90.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (1 entry)
- Days to follow up: 2,461 days (6.7 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,461; Year of follow up: 2016.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PASTTX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample TARGET-30-PASTTX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 2461
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.4
- Histology: Favorable
- MKI: Low
